Surgical pathology report (de-identified scan), TCGA case TCGA-76-6286, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6286-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

ADDED

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

[REDACTED] TCGA-76-6286

1. specimen designated "Right parietal tumor consistent with glioblastoma": glioblastoma, who grade iv.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Addendum

IMMUNOHISTOCHEMICAL STAINS

GFAP: POSITIVE STAINING OF TUMOR CELLS.

KI67: POSITIVE STAINING OF GREATER THAN 30% OF TUMOR CELL NUCLEI.

[REDACTED]
[REDACTED] Report Electronically Signed

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Foci of tumor necrosis are present. The histologic features of glioblastoma are best identified on the actual frozen section slides. An addendum with the results of immunohistochemical stains will be issued.

Frozen Section Diagnosis:

1. "Right parietal tumor consistent with glioblastoma": Glioblastoma.
Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:

Right parietal glioma

[page 2 of 2]
[REDACTED]

Source of Specimen:

1: Right parietal tumor consistent with glioblastoma

Gross Description:

[REDACTED]

1. Right parietal tumor consistent with glioblastoma: Received fresh for frozen section, labeled with the patient's name and "1 right parietal tumor" is a 1.3 x 0.6 x 0.3 cm aggregate of pale to tan soft brain tissue. Touch preparations and frozen sections are prepared. The specimen is entirely submitted in 2 cassettes.

A frozen section control

B. remaining specimen

Histology Laboratory

H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED]

[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file b55587fa-3d37-465f-a3a7-f1e0f087af18 (TCGA-76-6286.3B124818-8D8C-46B9-A8E8-60B6F22E75EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).